Somatic mutation profile of tumor specimen 0DCFVX from CCDI case PBBMLH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 3.1 years (1,139 days).
Specimen 0DCFVX: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a4b8215e-2940-42de-a1d7-551813c69776.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DCFVR (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3d26d271-44e9-438d-b1ce-5d5adcfd604b

The open-access MAF lists 1 somatic variant for this specimen: 1 protein-altering or splice-affecting.
By variant classification: Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCDC158 | c.1747C>T p.R583* | Nonsense Mutation (SNP) | VAF 141/721 reads (20%) | catalogued as rs755862671, COSV66356514; called by muse, mutect2, varscan2
